Somatic mutation profile of tumor specimen MP2PRT-PASKBE-TMP1-A (aliquot MP2PRT-PASKBE-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASKBE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,069 days).
Specimen MP2PRT-PASKBE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcf894f3-bab8-445b-acfc-b77d5855db5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKBE-NM1-B (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKBE-NM1-B-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef7892a1-20b3-41d2-a857-34b34633bfab

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Frame Shift Ins 3, Silent 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADIPOQ | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 65/491 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs202200116; called by muse, mutect2, varscan2
- JAK1 | c.2168C>A p.A723D | Missense Mutation (SNP) | VAF 75/459 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61089754; called by muse, mutect2, varscan2
- PDE3A | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 44/557 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs748512495, COSV62969496; called by muse, mutect2
- TMTC2 | c.2208dup p.A737Sfs*3 | Frame Shift Ins (INS) | VAF 177/404 reads (44%) | catalogued as rs750447474; called by mutect2, varscan2
- TRPM2 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 154/349 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs145770865; called by muse, mutect2, varscan2
- CRB2 | c.695_696insGGAGTTTA p.C232Wfs*215 | Frame Shift Ins (INS) | VAF 138/660 reads (21%) | called by mutect2, pindel*, varscan2
- CUEDC1 | c.20_21insCC p.S8Rfs*81 | Frame Shift Ins (INS) | VAF 81/479 reads (17%) | called by mutect2, pindel, varscan2
- PPARGC1A | c.2001G>T p.R667S | Missense Mutation (SNP) | VAF 178/381 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRAV9-2 | chr14:21941655 TGACAC>CCCA | Missense Mutation (DEL) | VAF 40/56 reads (71%) | called by pindel, varscan2*
- ZC3HAV1 | c.372C>G p.H124Q | Missense Mutation (SNP) | VAF 66/384 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OGN | c.156G>A p.L52= | Silent (SNP) | VAF 81/179 reads (45%) | catalogued as COSV99363904; called by muse, mutect2, varscan2
- TSSK6 | c.249C>T p.N83= | Silent (SNP) | VAF 280/631 reads (44%) | catalogued as rs1001708485, COSV53063214; called by muse, mutect2, varscan2
- TRAV14DV4 | chr14:21924651 ins C | 3'Flank (INS) | VAF 52/158 reads (33%) | called by mutect2, varscan2*
